Somatic mutation profile of tumor specimen TCGA-BK-A56F-01A (aliquot TCGA-BK-A56F-01A-32D-A27P-09) from TCGA case TCGA-BK-A56F, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G1; Age at diagnosis: 75.4 years (27,523 days).
Specimen TCGA-BK-A56F-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ad23f3ee-8b2a-4556-9c3d-5e065ab822da.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BK-A56F-10A (Blood Derived Normal), aliquot TCGA-BK-A56F-10A-01D-A27P-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d8bb67d2-d69b-4c3f-a4ec-c0479a8eb893

The open-access MAF lists 60 somatic variants for this specimen: 48 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 39, Silent 12, Nonsense Mutation 4, Frame Shift Del 3, In Frame Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.98C>G p.S33C | Missense Mutation (SNP) | VAF 8/45 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: likely pathogenic /  other; called by muse, mutect2, varscan2
- PIK3CA | c.1616C>G p.P539R | Missense Mutation (SNP) | VAF 13/53 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs121913285, COSV104381411, COSV55876380; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 6/15 reads (40%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- SLC4A1 | c.2608C>T p.R870W | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28931585, CM951173, COSV52258447; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACAP3 | c.1502G>A p.R501Q | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as COSV100330035; called by muse, mutect2, varscan2
- ACVR1 | c.1123C>T p.R375C | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs751000395, COSV55116085; called by muse, mutect2, varscan2
- ACVR1 | c.772A>T p.R258W | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM156014, COSV55116294, COSV99717854; called by muse, mutect2
- AMER3 | c.1042G>A p.A348T | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.89); catalogued as rs555917912, COSV58466667; called by muse, mutect2, varscan2
- ARID1A | c.2248C>T p.R750* | Nonsense Mutation (SNP) | VAF 12/30 reads (40%) | catalogued as COSV100250607, COSV61371935; called by muse, mutect2, varscan2
- B4GALT3 | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as rs749916838, COSV100157785; called by muse, mutect2, varscan2
- CALML5 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.135); catalogued as rs999235185, COSV66702730; called by muse, mutect2
- CARD11 | c.659T>G p.M220R | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); catalogued as COSV100712243; called by muse, mutect2, varscan2
- COMMD7 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.137); catalogued as rs1207872606, COSV54071397; called by muse, mutect2, varscan2
- CXADR | c.553C>G p.P185A | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.711); catalogued as rs1413245053, COSV53029672; called by muse, mutect2, varscan2
- DDX59 | c.1439C>T p.S480L | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.329); catalogued as rs201058329, COSV58751849; called by muse, mutect2, varscan2
- DLG3 | c.533+2T>C p.X178_splice | Splice Site (SNP) | VAF 5/58 reads (9%) | catalogued as COSV99529701; called by muse, mutect2
- DNAH1 | c.2254C>G p.R752G | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV101326130; called by muse, mutect2, varscan2
- DNAI2 | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV56761135; called by muse, mutect2, varscan2
- EMP2 | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs749960492, COSV63996073; called by muse, mutect2, varscan2
- FRAS1 | c.3673G>C p.V1225L | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.033); catalogued as COSV99352944; called by muse, mutect2, varscan2
- FSD2 | c.859G>A p.A287T | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated (0.61); PolyPhen benign (0.072); catalogued as COSV100575178; called by muse, mutect2, varscan2
- GJB6 | c.103A>T p.I35F | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99576085; called by muse, mutect2, varscan2
- KHDRBS2 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs533736043, COSV99834554; called by muse, mutect2, varscan2
- KMT2D | c.11850G>T p.Q3950H | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT tolerated, low confidence (0.47); PolyPhen possibly damaging (0.735); catalogued as COSV99982902; called by muse, mutect2, varscan2
- NSD3 | c.1078C>T p.R360* | Nonsense Mutation (SNP) | VAF 10/30 reads (33%) | catalogued as COSV57621522; called by muse, mutect2, varscan2
- OGDH | c.2519A>G p.H840R | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99759035; called by muse, mutect2, varscan2
- OR2L2 | c.684C>A p.H228Q | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as COSV100823853; called by muse, mutect2
- OR5H14 | c.475C>T p.H159Y | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV101454211; called by muse, mutect2, varscan2
- PAM | c.537G>T p.K179N | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV99173578; called by muse, mutect2, varscan2
- PHKA1 | c.2480G>A p.R827Q | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370717042, COSV59809486; called by muse, mutect2, varscan2
- PLCH1 | c.98G>A p.R33H (on ENST00000340059 / NM_001130960.2; = p.R45H on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); catalogued as rs200022055; called by muse, mutect2, varscan2
- PLEK2 | c.634C>T p.Q212* | Nonsense Mutation (SNP) | VAF 9/22 reads (41%) | catalogued as COSV99371810; called by muse, mutect2, varscan2
- PNPLA5 | c.791C>T p.T264M | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs749917334, COSV99336671; called by muse, mutect2, varscan2
- PRIM1 | c.166C>A p.R56S | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100590411; called by muse, mutect2, varscan2
- SCN11A | c.3020C>A p.P1007H | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.54); catalogued as COSV100181786; called by muse, mutect2, varscan2
- SLC26A9 | c.1605C>A p.C535* | Nonsense Mutation (SNP) | VAF 6/44 reads (14%) | catalogued as COSV100536449, COSV61605729; called by muse, mutect2, varscan2
- SOX17 | c.1097A>G p.Y366C | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs938860777, COSV99810662; called by muse, mutect2, varscan2
- SPAG7 | c.260T>C p.V87A | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.223); catalogued as COSV99236592; called by muse, mutect2, varscan2
- STK24 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.3); catalogued as rs533812307, COSV64822679; called by muse, mutect2, varscan2
- TRAF5 | c.1319A>G p.Y440C | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs372814574, COSV99807450; called by muse, mutect2, varscan2
- TSPAN19 | c.260T>G p.I87S | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV101468098; called by muse, mutect2, varscan2
- VENTX | c.442C>T p.R148W | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs45485699, COSV58084624; called by muse, mutect2, varscan2
- ZNF275 | c.1082C>T p.P361L (on ENST00000650114 / NM_001367757.1; = p.A328= on NM_001080485.3) | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as COSV100936201; called by muse, mutect2, varscan2
- ZNF282 | c.1639G>A p.E547K | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.59); PolyPhen benign (0.038); catalogued as COSV100021713; called by muse, mutect2, varscan2
- E2F1 | c.1272_1291delinsA p.F425Tfs*62 | Frame Shift Del (DEL) | VAF 12/32 reads (38%) | called by pindel, varscan2*
- FBXW7 | c.1139_1147dup p.D380_H382dup (on ENST00000281708 / NM_001349798.2; = p.D300_H302dup on NM_018315.5) | In Frame Ins (INS) | VAF 14/32 reads (44%) | called by mutect2, varscan2
- KMT2D | c.748del p.H250Tfs*11 | Frame Shift Del (DEL) | VAF 9/29 reads (31%) | called by mutect2, pindel, varscan2
- TLE1 | c.1610_1617del p.K537Tfs*84 | Frame Shift Del (DEL) | VAF 16/39 reads (41%) | called by mutect2, pindel, varscan2
- C20orf27 | c.168C>A p.G56= (on ENST00000379772 / NM_001258429.2; = p.G81= on NM_001039140.3) | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as COSV99422261; called by mutect2, varscan2
- CHL1 | c.2100G>A p.P700= (on ENST00000397491 / NM_001253387.1; = p.P716= on NM_006614.4) | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs751641022, COSV99851471; called by muse, varscan2
- COX11 | c.465T>C p.N155= | Silent (SNP) | VAF 20/40 reads (50%) | catalogued as COSV100174046; called by muse, mutect2, varscan2
- DYNC1I1 | c.1722C>T p.A574= | Silent (SNP) | VAF 38/82 reads (46%) | catalogued as rs370341645; called by muse, mutect2, varscan2
- EXOC2 | c.1419C>T p.Y473= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as rs745506514, COSV57867119; called by muse, mutect2, varscan2
- HINT1 | c.34C>A p.R12= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as rs151094514, COSV100401159; called by muse, mutect2, varscan2
- MTMR9 | c.51G>T p.L17= | Silent (SNP) | VAF 10/16 reads (63%) | catalogued as COSV99644365; called by muse, mutect2, varscan2
- MTUS1 | c.2592G>A p.S864= | Silent (SNP) | VAF 23/55 reads (42%) | catalogued as rs750235000, COSV100029565; called by muse, mutect2, varscan2
- NLGN3 | c.60G>A p.R20= | Silent (SNP) | VAF 26/73 reads (36%) | catalogued as COSV100704824; called by muse, mutect2, varscan2
- SBNO2 | c.1377C>T p.G459= | Silent (SNP) | VAF 22/57 reads (39%) | catalogued as rs1175386353, COSV100684655; called by muse, mutect2, varscan2
- SERPINA4 | c.1017G>A p.T339= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as rs764243430, COSV54068862; called by muse, mutect2, varscan2
- WWC3 | c.2794C>T p.L932= | Silent (SNP) | VAF 23/46 reads (50%) | catalogued as COSV101081524; called by muse, mutect2, varscan2
